Somatic mutation profile of tumor specimen SM-JU332 (aliquot 7316UP-393) from CPTAC case C266664, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen SM-JU332: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4e7c6fc-6a68-4753-bb0d-b5e20dd32ad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105287 (Blood Derived Normal), aliquot 7316UP-393-1105287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f981c3e3-64bd-4646-bd29-a9a6135d6b4f

The open-access MAF lists 1,288 somatic variants for this specimen: 913 protein-altering or splice-affecting, 245 silent, 130 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 771, Silent 245, Nonsense Mutation 59, Intron 55, Frame Shift Del 29, 5'UTR 25, Splice Site 23, 3'UTR 21, RNA 18, Splice Region 13, Frame Shift Ins 11, 5'Flank 10.

Variants (750 of 1,288; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3810T>A p.C1270* | Nonsense Mutation (SNP) | VAF 95/104 reads (91%) | catalogued as rs863225347, CM000125, CX995213, COSV57342456, COSV57383570; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 671/1154 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs797045203, CM139760, COSV55671915, COSV55675820, COSV55678737; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 702/738 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.3857G>C p.S1286T | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100383745; called by muse, mutect2, varscan2
- ACHE | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 312/533 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814894; called by muse, mutect2, varscan2
- ACOT11 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 110/756 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59350863; called by muse, mutect2, varscan2
- ADCY8 | c.1639G>T p.G547W | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53915654; called by muse, mutect2, varscan2
- ADGRB3 | c.3430G>T p.V1144F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV99486457; called by muse, mutect2, varscan2
- AGBL3 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51954764; called by muse, mutect2, varscan2
- AGTR2 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64157138; called by muse, mutect2, varscan2
- ALOXE3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 659/692 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs372027737; called by muse, mutect2, varscan2
- AMBN | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs372201499; called by muse, mutect2, varscan2
- ANGPT1 | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV52449117; called by muse, mutect2, varscan2
- APAF1 | c.2834G>T p.R945L (on ENST00000551964 / NM_181861.2; = p.R891L on NM_001160.3) | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs146420669; called by muse, mutect2, varscan2
- AR | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 293/309 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1305696138; called by muse, mutect2, varscan2
- ARMC5 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 435/487 reads (89%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1182126474, COSV99192819; called by muse, mutect2, varscan2
- ASCC3 | c.6275G>T p.G2092V | Missense Mutation (SNP) | VAF 171/184 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100976164; called by muse, mutect2, varscan2
- ASTN2 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 103/197 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100528087; called by muse, mutect2, varscan2
- ATP2A2 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 193/312 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875265, COSV57876016; called by muse, mutect2, varscan2
- ATXN1 | c.837C>G p.H279Q | Missense Mutation (SNP) | VAF 99/164 reads (60%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV55207534; called by muse, mutect2, varscan2
- AXDND1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 65/139 reads (47%) | catalogued as COSV62641362; called by muse, mutect2, varscan2
- B4GALT1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 96/101 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1177565118, COSV65709015; called by muse, mutect2, varscan2
- BCL6 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 225/333 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51656145; called by muse, mutect2, varscan2
- BIN1 | c.1397G>C p.G466A (on ENST00000316724 / NM_001320642.1; = p.G327A on NM_004305.4) | Missense Mutation (SNP) | VAF 459/941 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs762512900; called by muse, mutect2, varscan2
- BRINP1 | c.2005C>A p.L669M | Missense Mutation (SNP) | VAF 155/293 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV56302494, COSV56307679; called by muse, mutect2, varscan2
- BTBD11 | c.3138C>G p.C1046W (on ENST00000280758 / NM_001018072.2; = p.C583W on NM_001017523.2) | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55028759; called by muse, mutect2, varscan2
- BTBD11 | c.3139G>A p.E1047K (on ENST00000280758 / NM_001018072.2; = p.E584K on NM_001017523.2) | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs34000924; called by muse, mutect2, varscan2
- C1orf87 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 258/549 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs750065570; called by muse, mutect2, varscan2
- CACNA2D1 | c.1590G>C p.K530N | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV62385745; called by muse, mutect2, varscan2
- CACNA2D1 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV62371428; called by muse, mutect2, varscan2
- CBLL1 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV56031141; called by muse, mutect2, varscan2
- CCDC168 | c.14264C>A p.P4755Q | Missense Mutation (SNP) | VAF 165/174 reads (95%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV59423319; called by muse, mutect2, varscan2
- CCDC171 | c.2443A>C p.K815Q | Missense Mutation (SNP) | VAF 315/337 reads (93%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs756614235; called by muse, mutect2, varscan2
- CCDC40 | c.2309C>A p.A770E | Missense Mutation (SNP) | VAF 53/1324 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100884351; called by muse, mutect2
- CCRL2 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs376131944, COSV62193378; called by muse, mutect2, varscan2
- CD6 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs371896389; called by muse, mutect2, varscan2
- CDH23 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 173/348 reads (50%) | catalogued as CM118623; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1711C>A p.L571M | Missense Mutation (SNP) | VAF 235/432 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100575746; called by muse, mutect2, varscan2
- CEBPB | c.263del p.P88Rfs*53 | Frame Shift Del (DEL) | VAF 112/222 reads (50%) | catalogued as rs1213951106; called by mutect2, pindel, varscan2
- CFAP61 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 68/167 reads (41%) | catalogued as COSV55621866; called by muse, mutect2, varscan2
- CFAP69 | c.1533G>T p.M511I | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60188600; called by muse, mutect2, varscan2
- CHCHD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 108/259 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs756273254; called by muse, mutect2, varscan2
- CHGB | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 95/272 reads (35%) | catalogued as rs560272361, COSV66760876; called by muse, mutect2, varscan2
- CHRM3 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 132/142 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs202097685, COSV55093350, COSV99697259; called by muse, varscan2
- CNTN6 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368850185, COSV63162057; called by muse, mutect2, varscan2
- CNTNAP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70502012; called by muse, mutect2, varscan2
- COL11A1 | c.4159G>T p.G1387C | Missense Mutation (SNP) | VAF 306/539 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100615438; called by muse, mutect2, varscan2
- COL19A1 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 191/213 reads (90%) | SIFT tolerated (0.5); PolyPhen benign (0.247); catalogued as COSV100505503, COSV59572208; called by muse, mutect2, varscan2
- COL22A1 | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 201/476 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV57335844; called by muse, mutect2, varscan2
- COL6A5 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339825242; called by muse, mutect2, varscan2
- COL9A3 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59654062; called by muse, mutect2, varscan2
- CPED1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100119808; called by muse, mutect2, varscan2
- CSMD1 | c.3002C>A p.T1001N (on ENST00000520002; = p.T1000N on NM_033225.6) | Missense Mutation (SNP) | VAF 420/868 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59294813; called by muse, mutect2, varscan2
- CTU1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1396291989; called by muse, mutect2, varscan2
- CUX2 | c.3901G>C p.E1301Q | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as COSV55627940, COSV55628772; called by muse, mutect2, varscan2
- DHX15 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 29/234 reads (12%) | catalogued as COSV61025680; called by muse, mutect2, varscan2
- DIRAS3 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.172); catalogued as rs761694570; called by muse, mutect2, varscan2
- DLGAP1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752354203; called by muse, mutect2, varscan2
- DMBT1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs758442204; called by muse, mutect2, varscan2
- DMXL1 | c.8329C>T p.Q2777* | Nonsense Mutation (SNP) | VAF 94/104 reads (90%) | catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- DNAH7 | c.5764-1G>T p.X1922_splice | Splice Site (SNP) | VAF 62/149 reads (42%) | catalogued as COSV56751522; called by muse, mutect2, varscan2
- DNAJB4 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1352636432; called by muse, mutect2, varscan2
- DYSF | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 345/774 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053212, COSV50483645; called by muse, mutect2, varscan2
- EDIL3 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99676277; called by muse, mutect2, varscan2
- EFR3B | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV104391905; called by muse, mutect2, varscan2
- EIF4H | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.89); catalogued as COSV99733569; called by muse, mutect2, varscan2
- ELAPOR2 | c.850del p.V284Wfs*41 (on ENST00000450689 / NM_001142749.3; = p.V117Wfs*41 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 47/253 reads (19%) | catalogued as COSV99789566; called by mutect2, pindel, varscan2
- EML3 | c.1978G>T p.G660W | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604182; called by muse, mutect2, varscan2
- EPHB1 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV104432561; called by muse, mutect2, varscan2
- EPO | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773297902; called by muse, mutect2, varscan2
- ERICH3 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 345/434 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV58605596; called by muse, mutect2, varscan2
- ETS2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 314/678 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1411415689; called by muse, mutect2, varscan2
- EVX1 | c.903C>A p.S301R | Missense Mutation (SNP) | VAF 323/489 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99764062; called by muse, mutect2, varscan2
- EZHIP | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 265/272 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100539677; called by muse, mutect2, varscan2
- F5 | c.4375G>C p.D1459H | Missense Mutation (SNP) | VAF 200/485 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63123687, COSV63129999; called by muse, mutect2, varscan2
- F9 | c.1070del p.G357Efs*11 | Frame Shift Del (DEL) | VAF 145/203 reads (71%) | catalogued as rs1198183173, CM094094, CM940636, CM990576; called by mutect2, pindel, varscan2
- FABP1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99860851; called by muse, mutect2
- FAM135B | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777900338, COSV52730648; called by muse, mutect2, varscan2
- FAM151B | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1304437732; called by muse, mutect2
- FAM47A | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.077); catalogued as rs764600575, COSV100649805; called by muse, mutect2, varscan2
- FAM47C | c.2288G>T p.R763L | Missense Mutation (SNP) | VAF 383/413 reads (93%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100792410; called by muse, mutect2, varscan2
- FBN3 | c.6796_6810del p.G2266_N2270del | In Frame Del (DEL) | VAF 50/68 reads (74%) | catalogued as rs767570831; called by mutect2, varscan2
- FBXO40 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 213/280 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57524332; called by muse, mutect2, varscan2
- FIZ1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1471901175, COSV55607217, COSV99684747; called by muse, mutect2, varscan2
- FMN2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV100146758; called by muse, mutect2, varscan2
- FRMD6 | c.532G>C p.E178Q (on ENST00000344768 / NM_001267046.2; = p.E170Q on NM_152330.4) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs781384641, COSV100656397; called by muse, mutect2
- FYB1 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 360/570 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60952116; called by muse, mutect2, varscan2
- GAD2 | c.1747C>A p.Q583K | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1243932259, COSV99393155; called by muse, mutect2, varscan2
- GBA3 | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 205/293 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV72438551; called by muse, mutect2, varscan2
- GDPD4 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 126/191 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1034560793, COSV60016915, COSV60018216; called by muse, mutect2, varscan2
- GHR | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 99/299 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100050195; called by muse, mutect2, varscan2
- GRM8 | c.1946C>A p.S649Y | Missense Mutation (SNP) | VAF 151/257 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58808223; called by muse, mutect2, varscan2
- GTPBP10 | c.320-2A>G p.X107_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55987949; called by muse, mutect2
- GUCY2D | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 345/363 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs750895890; called by muse, mutect2, varscan2
- GYS2 | c.1425G>A p.V475= | Splice Region (SNP) | VAF 57/250 reads (23%) | catalogued as COSV53925751; called by muse, mutect2, varscan2
- HEPHL1 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 161/244 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59890126; called by muse, mutect2, varscan2
- HERC1 | c.14123G>C p.W4708S | Missense Mutation (SNP) | VAF 106/118 reads (90%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as COSV71250596; called by muse, mutect2, varscan2
- HS6ST3 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 141/158 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs141432230; called by muse, mutect2, varscan2
- HSPA4 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100507912; called by muse, mutect2
- HSPG2 | c.10855A>C p.S3619R | Missense Mutation (SNP) | VAF 482/992 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV65933030; called by muse, mutect2, varscan2
- IGLV11-55 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV101135393; called by muse, mutect2, varscan2
- IGSF8 | c.1555G>T p.V519L | Missense Mutation (SNP) | VAF 146/314 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as COSV58758476; called by muse, mutect2, varscan2
- IL21R | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 493/531 reads (93%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs371591899; called by muse, mutect2, varscan2
- IL5RA | c.1061T>A p.I354N | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs1204865704; called by muse, mutect2, varscan2
- INPP5D | c.2615G>T p.R872L (on ENST00000445964 / NM_001017915.3; = p.R871L on NM_005541.5) | Missense Mutation (SNP) | VAF 210/448 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV64036256; called by muse, mutect2, varscan2
- IPO13 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV64894001, COSV64894476; called by muse, mutect2
- IPO7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs772562320, COSV65686634; called by muse, mutect2, varscan2
- ITGA8 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1381764651; called by muse, mutect2, varscan2
- ITGA8 | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756898685; called by muse, mutect2, varscan2
- KALRN | c.4553C>T p.T1518M | Missense Mutation (SNP) | VAF 151/226 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780998165, COSV53758713; called by muse, mutect2, varscan2
- KCNA6 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV54976035; called by muse, mutect2, varscan2
- KCNE4 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 290/740 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427983334; called by muse, mutect2, varscan2
- KCNG4 | c.1264G>C p.G422R | Missense Mutation (SNP) | VAF 153/156 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377056; called by muse, mutect2, varscan2
- KCNT1 | c.3010G>T p.G1004C (on ENST00000488444; = p.G1023C on NM_020822.3) | Missense Mutation (SNP) | VAF 135/249 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104375601; called by muse, mutect2, varscan2
- KCTD4 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV100476709; called by muse, mutect2, varscan2
- KHDC1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 151/162 reads (93%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1562263204; called by muse, mutect2, varscan2
- KIAA1109 | c.9407C>A p.P3136H | Missense Mutation (SNP) | VAF 107/236 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52673100; called by muse, mutect2, varscan2
- KLF7 | c.544G>C p.A182P | Missense Mutation (SNP) | VAF 120/235 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.327); catalogued as COSV100519073; called by muse, mutect2, varscan2
- KLHL29 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 177/397 reads (45%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as rs1173388681; called by muse, mutect2, varscan2
- KNDC1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1359217204; called by muse, mutect2, varscan2
- KRT31 | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV104381206; called by muse, mutect2, varscan2
- KRTAP19-1 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 201/462 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.21); catalogued as COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- KRTAP22-2 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 87/180 reads (48%) | PolyPhen benign (0); catalogued as rs1388057362; called by muse, mutect2, varscan2
- KRTAP5-11 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 336/518 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as COSV100651805; called by muse, mutect2, varscan2
- KRTAP6-3 | c.45C>A p.N15K | Missense Mutation (SNP) | VAF 112/238 reads (47%) | PolyPhen probably damaging (0.909); catalogued as COSV66963409; called by muse, mutect2, varscan2
- KYAT3 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs769215372; called by muse, mutect2, varscan2
- LGI2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV66124311; called by muse, mutect2
- LINGO4 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV59093192; called by muse, mutect2, varscan2
- LMO4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 259/417 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100983997; called by muse, mutect2, varscan2
- LPP | c.698A>G p.H233R | Missense Mutation (SNP) | VAF 421/591 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs762236261; called by muse, mutect2, varscan2
- LRRC7 | c.2791C>A p.P931T (on ENST00000651989 / NM_001370785.2; = p.P898T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 294/405 reads (73%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV99224356; called by muse, mutect2, varscan2
- MAP2 | c.3886C>G p.Q1296E | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52296184; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1829G>T p.R610L | Missense Mutation (SNP) | VAF 173/396 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99151156; called by muse, mutect2, varscan2
- MARK1 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 338/361 reads (94%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs1165050058; called by muse, mutect2, varscan2
- MBD3L3 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 115/428 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs904709946; called by mutect2, varscan2
- MBTPS1 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 225/238 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570544; called by muse, mutect2, varscan2
- MCF2 | c.2333T>A p.I778N | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58477373; called by muse, mutect2
- MEGF8 | c.8170G>A p.A2724T (on ENST00000251268 / NM_001271938.2; = p.A2657T on NM_001410.3) | Missense Mutation (SNP) | VAF 154/334 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs530619835, COSV52104254; called by muse, mutect2, varscan2
- MGA | c.4031G>T p.W1344L | Missense Mutation (SNP) | VAF 91/96 reads (95%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV54953317; called by muse, mutect2, varscan2
- MMP3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 75/223 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV100243024; called by muse, mutect2, varscan2
- MPIG6B | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 178/181 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1400142656, COSV65390338; called by muse, mutect2, varscan2
- MROH2B | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 186/279 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV68189770; called by muse, mutect2, varscan2
- MSH4 | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs762051663; called by muse, mutect2, varscan2
- MTTP | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 259/428 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748681503, COSV55507564, COSV99644913; called by muse, mutect2, varscan2
- MTUS2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 97/107 reads (91%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101462271; called by muse, mutect2, varscan2
- MUC16 | c.41503G>T p.V13835F | Missense Mutation (SNP) | VAF 132/154 reads (86%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs781428326; called by muse, mutect2, varscan2
- MUC17 | c.3914C>G p.T1305S | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs763406863; called by muse, varscan2
- MUC17 | c.11123G>A p.S3708N | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV60294101; called by muse, mutect2, varscan2
- MUC22 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 208/218 reads (95%) | SIFT deleterious, low confidence (0.02); catalogued as rs1469259269; called by muse, mutect2, varscan2
- MUC5B | c.10816G>A p.G3606R | Missense Mutation (SNP) | VAF 200/560 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs372672550; called by muse, mutect2, varscan2
- MYBL2 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 135/235 reads (57%) | catalogued as COSV53829661; called by muse, mutect2, varscan2
- MYH1 | c.5422G>T p.A1808S | Missense Mutation (SNP) | VAF 253/269 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV56857151; called by muse, mutect2, varscan2
- MYO3A | c.3684G>T p.R1228S | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs927199184, COSV56318217; called by muse, mutect2
- NALCN | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 100/110 reads (91%) | catalogued as COSV51917306, COSV51932503; called by muse, mutect2, varscan2
- NAV3 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99888513; called by muse, mutect2, varscan2
- NBEAL1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 48/105 reads (46%) | catalogued as rs773758454; called by muse, mutect2, varscan2
- NCKAP5L | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.296); catalogued as rs774089943; called by muse, mutect2, varscan2
- NEXMIF | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 145/147 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50023282; called by muse, mutect2, varscan2
- NLGN1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 325/406 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64349101; called by muse, mutect2, varscan2
- NLGN4X | c.2218G>T p.D740Y | Missense Mutation (SNP) | VAF 357/370 reads (96%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.333); catalogued as COSV52012012; called by muse, mutect2, varscan2
- NOTCH2 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 200/331 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782757612; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 59/62 reads (95%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by muse, mutect2, varscan2
- NPBWR2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 132/251 reads (53%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs370307704; called by muse, mutect2, varscan2
- NPY2R | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 217/578 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV61527622; called by muse, mutect2, varscan2
- NRROS | c.1641del p.L548* | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as COSV100145401; called by mutect2, pindel*
- OR10G3 | c.831del p.T278Rfs*19 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | catalogued as COSV100336118; called by mutect2, pindel, varscan2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2, varscan2
- OR4K1 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99579397; called by muse, mutect2, varscan2
- OR8K3 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV57131466; called by muse, mutect2, varscan2
- OSBPL5 | c.2467C>T p.L823F | Missense Mutation (SNP) | VAF 112/210 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.24); catalogued as rs1227879264; called by muse, mutect2, varscan2
- PCDHGB1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 333/343 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs930490756; called by muse, mutect2, varscan2
- PCNT | c.6889G>A p.A2297T | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs959271732; called by muse, mutect2, varscan2
- PDE1B | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 101/168 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV99226348; called by muse, mutect2, varscan2
- PDP1 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 355/763 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99892212; called by muse, mutect2, varscan2
- PERM1 | c.1359C>A p.D453E | Missense Mutation (SNP) | VAF 258/742 reads (35%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.62); catalogued as rs776964907; called by muse, mutect2, varscan2
- PKHD1L1 | c.2494G>T p.G832* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV65749315; called by muse, mutect2, varscan2
- PLBD2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs1304164084; called by muse, mutect2, varscan2
- PNPLA6 | c.3112G>T p.E1038* (on ENST00000414982 / NM_001166111.2; = p.E990* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 253/269 reads (94%) | catalogued as COSV99075571; called by muse, mutect2, varscan2
- POLD1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70956804; called by muse, mutect2, varscan2
- POTEF | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 195/1312 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62544059; called by muse, varscan2
- PPFIBP1 | c.2287G>T p.V763F (on ENST00000318304 / NM_177444.3; = p.V757F on NM_003622.4) | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363429727, COSV57292903; called by muse, mutect2
- PRAMEF4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 733/771 reads (95%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV52437958; called by muse, mutect2, varscan2
- PRDM8 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 134/373 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs752993100; called by muse, varscan2
- PRDM9 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 355/1078 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs184753683; called by muse, mutect2, varscan2
- PRSS58 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 133/213 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV73488797; called by muse, mutect2, varscan2
- PTCHD3 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV71256775; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- RASGRF2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 338/728 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54130199; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 168/292 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV101208255; called by muse, mutect2, varscan2
- RNASE3 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 166/500 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs12147890; called by muse, mutect2
- RNASE3 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 166/496 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV58959335; called by muse, mutect2
- ROBO2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 352/373 reads (94%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV59922831; called by muse, mutect2, varscan2
- RP1L1 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 474/953 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101223271; called by muse, mutect2, varscan2
- RPS6KA2 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99689977; called by muse, mutect2, varscan2
- RRP12 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs774617555; called by muse, mutect2, varscan2
- RUFY2 | c.231del p.L78Cfs*12 | Frame Shift Del (DEL) | VAF 68/150 reads (45%) | catalogued as rs751531309; called by mutect2, varscan2
- S100A5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 50/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62876468; called by muse, mutect2, varscan2
- S100A7L2 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 34/295 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV64194761; called by muse, mutect2, varscan2
- SALL4 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 306/892 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53854576; called by muse, mutect2, varscan2
- SATL1 | c.350C>A p.S117* (on ENST00000395409; = p.S304* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 262/267 reads (98%) | catalogued as COSV60577984; called by muse, mutect2, varscan2
- SECTM1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 394/1164 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1439174252; called by muse, mutect2, varscan2
- SERPINA3 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs10956; called by muse, mutect2
- SETD1B | c.5059G>T p.G1687C | Missense Mutation (SNP) | VAF 165/295 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs553963413; called by muse, mutect2, varscan2
- SF1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs371270819; called by muse, varscan2
- SH3RF3 | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100514096; called by muse, mutect2, varscan2
- SIGLEC10 | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.407); catalogued as rs1314831849; called by muse, varscan2
- SIGLEC7 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs771941732; called by muse, mutect2, varscan2
- SLC22A25 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs1272844107; called by muse, mutect2, varscan2
- SLC30A10 | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 125/134 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63076390; called by muse, mutect2, varscan2
- SLC35G5 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 228/483 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as rs764168543; called by muse, mutect2, varscan2
- SLITRK2 | c.313del p.A105Hfs*5 | Frame Shift Del (DEL) | VAF 160/229 reads (70%) | catalogued as COSV59424912; called by mutect2, pindel, varscan2
- SLITRK4 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100567516; called by muse, mutect2, varscan2
- SMYD3 | c.910C>T p.Q304* (on ENST00000490107 / NM_001375962.1; = p.Q245* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as rs746995439; called by muse, mutect2
- SNTG1 | c.707T>A p.V236E | Missense Mutation (SNP) | VAF 170/337 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1241317655; called by muse, mutect2, varscan2
- SPAG16 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100530410; called by muse, mutect2, varscan2
- SSX3 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 321/332 reads (97%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53643939, COSV53646757; called by muse, mutect2, varscan2
- ST3GAL4 | c.193G>T p.D65Y (on ENST00000392669 / NM_001254758.1; = p.D61Y on NM_006278.3) | Missense Mutation (SNP) | VAF 222/363 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV57109437; called by muse, mutect2, varscan2
- ST8SIA1 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 179/274 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0.174); catalogued as rs565011134; called by muse, mutect2, varscan2
- STK11 | c.443T>C p.F148S | Missense Mutation (SNP) | VAF 217/227 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58829789; called by muse, mutect2, varscan2
- STK32B | c.910-1G>T p.X304_splice | Splice Site (SNP) | VAF 13/113 reads (12%) | catalogued as COSV51497101; called by muse, mutect2, varscan2
- SUGCT | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1203172280; called by muse, mutect2
- SULF2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 192/343 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.774); catalogued as rs373180984; called by muse, mutect2, varscan2
- SVEP1 | c.3212C>A p.S1071* | Nonsense Mutation (SNP) | VAF 96/234 reads (41%) | catalogued as COSV57029663; called by muse, mutect2, varscan2
- SYT12 | c.765G>C p.E255D | Missense Mutation (SNP) | VAF 203/696 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs778042037; called by muse, mutect2, varscan2
- TACO1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 204/400 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV51976360; called by muse, mutect2, varscan2
- TBC1D1 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 350/591 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs151143743; called by muse, mutect2, varscan2
- TIAM1 | c.4346G>T p.R1449L | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV54554620; called by muse, varscan2
- TIFAB | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 335/356 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV72345691; called by muse, mutect2, varscan2
- TLR5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMEM161A | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 173/186 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50776683; called by muse, mutect2, varscan2
- TMEM178B | c.585G>T p.W195C | Missense Mutation (SNP) | VAF 218/335 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV73803549; called by muse, mutect2, varscan2
- TMEM179 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 114/121 reads (94%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as rs1433425536; called by muse, mutect2, varscan2
- TMPRSS11A | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as COSV100602790; called by muse, mutect2, varscan2
- TRBV20-1 | c.146G>T p.W49L | Missense Mutation (SNP) | VAF 208/355 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760783607; called by muse, mutect2, varscan2
- TRIM65 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 291/939 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1256281792, COSV99485496; called by muse, mutect2, varscan2
- TRIM9 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 304/318 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762640179, COSV53612436; called by muse, mutect2, varscan2
- TRPC7 | c.1141C>A p.L381M | Missense Mutation (SNP) | VAF 127/138 reads (92%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV100726098; called by muse, mutect2, varscan2
- TRPV5 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 366/609 reads (60%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV99520590; called by muse, mutect2, varscan2
- TTC29 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100283640; called by muse, mutect2, varscan2
- TTLL5 | c.2990C>T p.S997L | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs759872181, COSV100089536; called by muse, varscan2
- TWIST1 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CD013661, CD982422, CM060093; called by muse, mutect2, varscan2
- UNC45A | c.2350A>G p.M784V | Missense Mutation (SNP) | VAF 245/250 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67793621; called by muse, mutect2, varscan2
- UNC5D | c.2752C>A p.L918M | Missense Mutation (SNP) | VAF 313/709 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54782165; called by muse, mutect2, varscan2
- USP4 | c.1692G>T p.V564= | Splice Region (SNP) | VAF 12/126 reads (10%) | catalogued as COSV55537742; called by muse, mutect2
- VGLL3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 124/131 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs962129357; called by muse, mutect2, varscan2
- VIRMA | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV99889412; called by muse, mutect2, varscan2
- WBP1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 152/296 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs776821607; called by muse, mutect2, varscan2
- WDR90 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 218/238 reads (92%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV53471855; called by muse, varscan2
- WNT10A | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 159/349 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51463831; called by muse, mutect2, varscan2
- XDH | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV65150813; called by muse, mutect2
- XIRP2 | c.8311G>C p.E2771Q (on ENST00000628543; = p.E2946Q on NM_152381.6) | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV99737015; called by muse, mutect2, varscan2
- ZNF225 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 65/197 reads (33%) | catalogued as COSV53471936; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>A p.S723* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100835538, COSV62817472; called by muse, mutect2, varscan2
- ZNF684 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 110/225 reads (49%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.67); catalogued as rs1323868688; called by muse, mutect2, varscan2
- ZNF761 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 167/259 reads (64%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV100483334; called by muse, mutect2, varscan2
- ZNF804B | c.2438A>T p.N813I | Missense Mutation (SNP) | VAF 71/117 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60863770; called by muse, mutect2, varscan2
- ZNF830 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV58490749; called by muse, mutect2, varscan2
- AASDH | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 74/127 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ABCA1 | c.4129C>G p.L1377V | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2
- ABCA1 | c.4128C>A p.S1376R | Missense Mutation (SNP) | VAF 38/724 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- ABCA13 | c.14034C>A p.D4678E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCC8 | c.2872G>T p.A958S | Missense Mutation (SNP) | VAF 364/582 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCG1 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 253/612 reads (41%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ABI3 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, varscan2
- ACSM5 | c.833C>A p.A278E | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ACTA2 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 263/600 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAD1 | c.306C>G p.H102Q | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM9 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2221dup p.E741Gfs*6 | Frame Shift Ins (INS) | VAF 116/194 reads (60%) | called by pindel, varscan2
- ADCY3 | c.954C>G p.V318= | Splice Region (SNP) | VAF 114/237 reads (48%) | called by muse, mutect2, varscan2
- ADGRB1 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ADGRG4 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ADGRL2 | c.2555G>T p.W852L (on ENST00000370717 / NM_001366005.1; = p.W839L on NM_012302.4) | Missense Mutation (SNP) | VAF 124/641 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ADGRL4 | c.22+7G>T | Splice Region (SNP) | VAF 79/199 reads (40%) | called by muse, mutect2, varscan2
- ADH1C | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 53/83 reads (64%) | called by muse, mutect2, varscan2
- AFF3 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AGFG1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 180/441 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AGO4 | c.2446A>G p.R816G | Missense Mutation (SNP) | VAF 38/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- AHCYL2 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AJAP1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 375/1234 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C2 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- ALDH8A1 | c.1311G>C p.K437N | Missense Mutation (SNP) | VAF 376/399 reads (94%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ALPL | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 504/514 reads (98%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- AMBP | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 205/405 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AMOTL2 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 182/712 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMY2B | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 232/989 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD30A | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD30B | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ANKRD30BL | c.678A>C p.P226= | Splice Region (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- ANKRD60 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- AP1B1 | c.2264C>G p.A755G | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB2 | c.1378A>C p.T460P (on ENST00000295974 / NM_001166050.2; = p.T461P on NM_004307.2) | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLP2 | c.1840A>T p.T614S | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- APLP2 | c.2107G>T p.V703L | Missense Mutation (SNP) | VAF 182/297 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- APOB | c.12082C>A p.P4028T | Missense Mutation (SNP) | VAF 80/683 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP11 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 63/107 reads (59%) | called by muse, mutect2, varscan2
- ARFIP2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 190/300 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP23 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 111/241 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP28 | c.2178A>C p.Q726H (on ENST00000383472 / NM_001366230.1; = p.Q567H on NM_001010000.3) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARID5B | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 193/418 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ARMC2 | c.567del p.S190Vfs*6 | Frame Shift Del (DEL) | VAF 76/109 reads (70%) | called by mutect2, pindel, varscan2
- ASB7 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 525/550 reads (95%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ASCC2 | c.2241C>A p.D747E | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2
- ATAD2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 112/236 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 348/441 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 337/793 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ATRX | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATRX | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUTS2 | c.3133A>G p.M1045V | Missense Mutation (SNP) | VAF 192/335 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- B4GALNT3 | c.2534+1G>T p.X845_splice | Splice Site (SNP) | VAF 17/142 reads (12%) | called by muse, mutect2, varscan2
- BACE2 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBOX1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- BHMG1 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BIRC6 | c.7309G>T p.D2437Y | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BOD1L1 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- BPI | c.552G>T p.W184C (on ENST00000262865; = p.W180C on NM_001725.3) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BPTF | c.6508G>T p.G2170* | Nonsense Mutation (SNP) | VAF 103/245 reads (42%) | called by muse, mutect2, varscan2
- BRD1 | c.2646_2649dup p.H884Tfs*9 (on ENST00000216267 / NM_001349940.1; = p.H1015Tfs*9 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 63/426 reads (15%) | called by mutect2, pindel, varscan2
- BRDT | c.445+8A>T | Splice Region (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2
- BST1 | c.487T>A p.C163S | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG3 | c.21del p.V8Lfs*8 | Frame Shift Del (DEL) | VAF 53/136 reads (39%) | called by mutect2, pindel, varscan2
- C17orf99 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 419/697 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- C17orf99 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 422/703 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- C1QC | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 200/473 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C20orf203 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- C4orf17 | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- C8A | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 217/470 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C9 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 170/683 reads (25%) | called by muse, mutect2, varscan2
- CABS1 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CACNA1H | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNG5 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CALCOCO2 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CAMK4 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CAMK4 | c.1205_1212del p.K402Rfs*7 | Frame Shift Del (DEL) | VAF 44/51 reads (86%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.911A>T p.K304M | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.243); called by muse, mutect2
- CASQ2 | c.1077G>C p.E359D | Missense Mutation (SNP) | VAF 119/426 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CASTOR2 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 531/889 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CAVIN4 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CBX2 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 303/978 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CBX4 | c.558_576del p.D187Tfs*19 | Frame Shift Del (DEL) | VAF 67/258 reads (26%) | called by pindel, varscan2
- CCDC105 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 90/97 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CCDC150 | c.540G>T p.R180S | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC166 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 91/172 reads (53%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); called by muse, mutect2
- CCDC169 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CCDC171 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 111/120 reads (93%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC180 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 128/136 reads (94%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- CCDC61 | c.1160A>C p.Q387P | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); called by muse, varscan2
- CCDC61 | c.1161G>C p.Q387H | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, varscan2
- CCDC61 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- CCDC73 | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC81 | c.917_919dup p.E306_M307insK (on ENST00000445632 / NM_001156474.2; = p.E216_M217insK on NM_021827.4) | In Frame Ins (INS) | VAF 98/182 reads (54%) | called by mutect2, pindel, varscan2
- CCDC96 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 150/338 reads (44%) | called by mutect2, varscan2
- CCL18 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 191/384 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCNE2 | c.575C>A p.S192* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- CCT8L2 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 36/818 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- CD177 | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CD274 | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 90/100 reads (90%) | called by muse, mutect2, varscan2
- CD320 | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 469/499 reads (94%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CD38 | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CDC14C | c.1230C>G p.Y410* (on ENST00000428251; = p.Y303* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 128/608 reads (21%) | called by muse, varscan2
- CDH4 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CDHR2 | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 87/88 reads (99%) | SIFT tolerated (0.86); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CDK11A | c.919A>T p.T307S (on ENST00000378633 / NM_001313896.2; = p.T304S on NM_024011.4) | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by mutect2, varscan2
- CDK13 | c.2221del p.E741Kfs*27 | Frame Shift Del (DEL) | VAF 33/64 reads (52%) | called by mutect2, pindel, varscan2
- CDON | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 197/320 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- CECR2 | c.3887C>G p.P1296R (on ENST00000342247 / NM_001290047.2; = p.P1112R on NM_001290046.1) | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CELF2 | c.1287C>A p.H429Q (on ENST00000416382 / NM_001025077.3; = p.H442Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPE | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- CEP350 | c.7193A>G p.E2398G | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CFAP46 | c.4598T>A p.L1533Q | Missense Mutation (SNP) | VAF 105/244 reads (43%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CFAP46 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CFAP54 | c.6497G>C p.G2166A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.239); called by muse, mutect2
- CGREF1 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 220/487 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, varscan2
- CHAF1A | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 84/85 reads (99%) | SIFT tolerated (0.38); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHAT | c.1082G>T p.W361L | Missense Mutation (SNP) | VAF 224/528 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAT | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 272/580 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.4639G>A p.A1547T (on ENST00000357008 / NM_001363606.2; = p.A1560T on NM_001273.5) | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- CHD4 | c.3110G>T p.G1037V (on ENST00000357008 / NM_001363606.2; = p.G1050V on NM_001273.5) | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD8 | c.2346_2362del p.P783Efs*16 (on ENST00000646647 / NM_001170629.2; = p.P504Efs*16 on NM_020920.4) | Frame Shift Del (DEL) | VAF 141/228 reads (62%) | called by mutect2, pindel, varscan2
- CHD9 | c.8374G>T p.A2792S (on ENST00000398510 / NM_001382353.1; = p.A2776S on NM_025134.7) | Missense Mutation (SNP) | VAF 116/125 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CHPF2 | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CHRDL2 | c.1239G>T p.Q413H (on ENST00000376332 / NM_001304415.1; = p.D432Y on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 177/332 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CHRM1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHRM3 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 88/96 reads (92%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); called by muse, varscan2
- CMKLR1 | c.631C>A p.P211T (on ENST00000312143 / NM_001142344.2; = p.P209T on NM_004072.3) | Missense Mutation (SNP) | VAF 248/427 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMYA5 | c.6571A>T p.T2191S | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CMYA5 | c.8510C>T p.P2837L | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CNGB3 | c.481A>T p.S161C | Missense Mutation (SNP) | VAF 266/530 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTN1 | c.1882dup p.S628Ffs*5 | Frame Shift Ins (INS) | VAF 46/272 reads (17%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 267/639 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL12A1 | c.5442del p.K1814Nfs*22 | Frame Shift Del (DEL) | VAF 65/98 reads (66%) | called by mutect2, pindel, varscan2
- COL16A1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 484/500 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COL2A1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 178/341 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- COMMD10 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 132/140 reads (94%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- COPS8 | c.150-1G>A p.X50_splice | Splice Site (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- CPEB2 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 212/352 reads (60%) | SIFT tolerated, low confidence (0.12); called by muse, varscan2
- CPT1A | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREM | c.729G>T p.M243I (on ENST00000429130; = p.M19I on NM_182717.2) | Missense Mutation (SNP) | VAF 197/444 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRKL | c.548G>T p.R183I | Missense Mutation (SNP) | VAF 253/540 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CRYBA4 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 380/799 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CRYGA | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 101/233 reads (43%) | called by muse, mutect2, varscan2
- CSMD3 | c.8660G>T p.S2887I (on ENST00000297405 / NM_001363185.1; = p.S2718I on NM_052900.3) | Missense Mutation (SNP) | VAF 16/505 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- CSTA | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CYP11B2 | c.1122G>C p.R374= | Splice Region (SNP) | VAF 94/840 reads (11%) | called by muse, mutect2
- CYP1B1 | c.145dup p.S49Ffs*175 | Frame Shift Ins (INS) | VAF 57/358 reads (16%) | called by mutect2, pindel, varscan2
- DAAM2 | c.1787dup p.R597Afs*19 | Frame Shift Ins (INS) | VAF 38/316 reads (12%) | called by mutect2, varscan2
- DBX2 | c.726del p.N243Ifs*16 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- DCAF17 | c.1031G>C p.W344S | Missense Mutation (SNP) | VAF 155/298 reads (52%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DCBLD1 | c.906_907del p.D303Qfs*2 | Frame Shift Del (DEL) | VAF 277/399 reads (69%) | called by mutect2, pindel, varscan2
- DDR2 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 291/624 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DDX31 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 27/842 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- DDX3X | c.1741G>T p.G581C (on ENST00000399959; = p.G582C on NM_001356.5) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DDX60L | c.3217A>T p.K1073* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- DGKZ | c.3339G>T p.Q1113H (on ENST00000454345 / NM_001105540.2; = p.Q925H on NM_003646.4) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHX16 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 283/297 reads (95%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DLEU7 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- DLG2 | c.2550C>G p.C850W | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DLGAP3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 447/878 reads (51%) | called by muse, mutect2, varscan2
- DLGAP5 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 82/89 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DMXL1 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJB11 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DNAJC12 | c.298-1G>A p.X100_splice | Splice Site (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- DNM3 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 335/800 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DOCK9 | c.5519G>C p.G1840A (on ENST00000376460 / NM_001366676.2; = p.G1841A on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/84 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOP1B | c.6415G>T p.G2139W | Missense Mutation (SNP) | VAF 180/399 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 261/270 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPEP3 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 128/141 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DRD2 | c.-29C>A | Splice Region (SNP) | VAF 66/316 reads (21%) | called by muse, mutect2, varscan2
- DROSHA | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 137/492 reads (28%) | called by muse, mutect2, varscan2
- DUSP3 | c.354C>T p.G118= | Splice Region (SNP) | VAF 219/475 reads (46%) | called by muse, mutect2, varscan2
- EBF1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 122/129 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECEL1 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 273/450 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EGR3 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); called by muse, mutect2
- ELP3 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN2 | c.1367G>C p.R456T | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EMX1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPG5 | c.6874A>T p.I2292F | Missense Mutation (SNP) | VAF 451/502 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EPG5 | c.3400A>T p.S1134C | Missense Mutation (SNP) | VAF 103/110 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA3 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 176/185 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EPS15 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ERBIN | c.3285G>T p.R1095S | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERC2 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 243/251 reads (97%) | SIFT tolerated (0.51); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ERICH1 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 239/541 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESPNL | c.1882A>T p.T628S | Missense Mutation (SNP) | VAF 254/549 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ESX1 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 267/277 reads (96%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ETV1 | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- EXOC2 | c.1318A>T p.T440S | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- EXOC7 | c.1091A>T p.Y364F (on ENST00000335146 / NM_001145297.4; = p.Y282F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/768 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EYS | c.5520G>C p.W1840C | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EYS | c.3203A>G p.D1068G | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- F2 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 197/631 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM114A1 | c.945+1G>T p.X315_splice | Splice Site (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- FAM135B | c.2452G>T p.D818Y | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- FAM78A | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASTKD3 | c.1119G>T p.R373S | Missense Mutation (SNP) | VAF 151/672 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- FAT4 | c.9285C>G p.H3095Q | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT4 | c.10204G>T p.D3402Y | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO47 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2
- FCRL5 | c.2317T>A p.C773S | Missense Mutation (SNP) | VAF 11/367 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2
- FCRL5 | c.2316C>A p.H772Q | Missense Mutation (SNP) | VAF 11/363 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2
- FER | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 110/123 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FFAR1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 501/519 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FFAR2 | c.256A>T p.S86C | Missense Mutation (SNP) | VAF 72/537 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, varscan2
- FGD5 | c.2645G>C p.S882T | Missense Mutation (SNP) | VAF 372/539 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FGF23 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 287/956 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FLG2 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 390/900 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FLOT2 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FMO4 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 138/391 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FOXD1 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 336/357 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXL2 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 134/835 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FOXM1 | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 16/473 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- FOXP2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 254/427 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FPGT | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMPD4 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 164/167 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- FRY | c.599T>A p.I200N | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2
- FRY | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 168/296 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FRYL | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2
- FSD2 | c.1708A>T p.K570* | Nonsense Mutation (SNP) | VAF 217/229 reads (95%) | called by muse, mutect2, varscan2
- FSIP2 | c.11223T>A p.N3741K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- FSIP2 | c.16468C>A p.P5490T | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FSIP2 | c.17587G>C p.V5863L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FUOM | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 70/144 reads (49%) | called by muse, mutect2, varscan2
- GABRA6 | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 235/759 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRR2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 235/245 reads (96%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GEN1 | c.2144G>T p.C715F | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GHR | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 74/920 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.263); called by muse, mutect2
- GJB5 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 417/947 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK2 | c.1253C>A p.P418Q | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLE1 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 416/799 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GNRHR | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 281/471 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGB1 | c.7014G>T p.L2338F | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GP2 | c.971T>G p.L324R (on ENST00000381362 / NM_001007240.3; = p.L321R on NM_001502.4) | Missense Mutation (SNP) | VAF 141/147 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR15 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- GRIA4 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRID2IP | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.2219C>A p.A740E | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GRM3 | c.1324+1G>T p.X442_splice | Splice Site (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- GRM5 | c.1885T>A p.Y629N | Missense Mutation (SNP) | VAF 116/191 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM7 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRM7 | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 194/305 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GZMA | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 85/96 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- H2AC6 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 138/555 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2BC13 | c.35A>T p.K12M | Missense Mutation (SNP) | VAF 32/423 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2
- HACE1 | c.715-1G>T p.X239_splice | Splice Site (SNP) | VAF 77/81 reads (95%) | called by muse, mutect2, varscan2
- HAVCR2 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 73/85 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HBE1 | c.262A>T p.K88* | Nonsense Mutation (SNP) | VAF 194/640 reads (30%) | called by muse, mutect2, varscan2
- HEATR9 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 281/573 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELQ | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HELZ | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- HERC2 | c.5578G>T p.G1860* | Nonsense Mutation (SNP) | VAF 58/62 reads (94%) | called by muse, mutect2, varscan2
- HEY1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HGFAC | c.1241C>G p.S414W | Missense Mutation (SNP) | VAF 372/894 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIVEP2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 180/196 reads (92%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HLA-DQA1 | c.361T>G p.S121A | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HLA-DQA2 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 264/280 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- HMCN2 | c.4988G>T p.G1663V | Missense Mutation (SNP) | VAF 198/583 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA2 | c.391+7C>A | Splice Region (SNP) | VAF 85/267 reads (32%) | called by muse, mutect2, varscan2
- IFITM3 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 86/256 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- IGFBP2 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGKV2D-24 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 202/502 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- IGSF9B | c.4147G>C p.V1383L | Missense Mutation (SNP) | VAF 231/371 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IK | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 362/377 reads (96%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- IKZF2 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INHBA | c.1144A>T p.S382C | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INVS | c.2132G>T p.S711I | Missense Mutation (SNP) | VAF 203/215 reads (94%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IPO13 | c.1814A>T p.E605V | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2
- IPO8 | c.1568A>G p.Q523R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- IRS4 | c.2308T>A p.S770T | Missense Mutation (SNP) | VAF 293/303 reads (97%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IRX2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IRX4 | c.83A>C p.E28A | Missense Mutation (SNP) | VAF 126/611 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- IRX4 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 123/603 reads (20%) | called by muse, mutect2, varscan2
- ITGAD | c.1385G>C p.C462S | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ITIH5 | c.1191C>G p.S397R | Missense Mutation (SNP) | VAF 288/616 reads (47%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ITIH6 | c.505del p.Q169Nfs*3 | Frame Shift Del (DEL) | VAF 351/494 reads (71%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 212/390 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- JCAD | c.2327C>A p.T776K | Missense Mutation (SNP) | VAF 278/558 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, varscan2
- JMJD7-PLA2G4B | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 187/196 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- JSRP1 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KANK1 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 200/216 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KAT6A | c.1545del p.K516Sfs*29 | Frame Shift Del (DEL) | VAF 200/539 reads (37%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.474del p.Q158Hfs*6 | Frame Shift Del (DEL) | VAF 30/226 reads (13%) | called by mutect2, pindel, varscan2
- KCNN4 | c.1022A>T p.Q341L | Missense Mutation (SNP) | VAF 280/290 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- KCP | c.3018C>A p.S1006R (on ENST00000620378; = p.S1066R on NM_001366122.1) | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KDM2B | c.3547G>T p.V1183L | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2
- KIAA1841 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- KIF13B | c.4001C>A p.A1334D | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KIF5C | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- KLF8 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 92/99 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL31 | c.86A>T p.K29I | Missense Mutation (SNP) | VAF 121/194 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL33 | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 165/538 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL5 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KLK13 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 146/238 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP19-8 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 269/569 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KY | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 311/407 reads (76%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA1 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 294/711 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA4 | c.4900A>T p.T1634S (on ENST00000230538 / NM_001105206.3; = p.T1627S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 262/278 reads (94%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LAMA5 | c.7418A>C p.Q2473P | Missense Mutation (SNP) | VAF 130/217 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LOXL3 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 191/409 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LRFN5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- LRFN5 | c.652C>G p.R218G | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- LRGUK | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRP2 | c.6682C>A p.L2228I | Missense Mutation (SNP) | VAF 141/278 reads (51%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4C | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRRC4C | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1492G>C p.G498R | Missense Mutation (SNP) | VAF 179/315 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- LRRC7 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRC71 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC74B | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 192/442 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRC8A | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 260/481 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LY6G5B | c.333A>T p.Q111H | Missense Mutation (SNP) | VAF 12/386 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LY6G6C | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MACF1 | c.4993G>T p.G1665C | Missense Mutation (SNP) | VAF 195/200 reads (98%) | called by muse, mutect2, varscan2
- MAN1C1 | c.1849del p.V617* | Frame Shift Del (DEL) | VAF 229/326 reads (70%) | called by mutect2, pindel, varscan2
- MAP3K10 | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 95/99 reads (96%) | SIFT tolerated (0.15); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- MAP3K11 | c.959dup p.P321Afs*6 | Frame Shift Ins (INS) | VAF 28/239 reads (12%) | called by mutect2, pindel, varscan2
- MBD5 | c.2845+1G>C p.X949_splice | Splice Site (SNP) | VAF 114/251 reads (45%) | called by muse, mutect2, varscan2
- MBNL1 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 96/717 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MDH1 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- METTL17 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 250/544 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFRP | c.137G>T p.G46V (on ENST00000449574; = p.G422V on NM_031433.4) | Missense Mutation (SNP) | VAF 154/240 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MGAM2 | c.4717C>A p.L1573I | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MICAL2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 142/248 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MICU1 | c.605G>T p.G202V (on ENST00000361114 / NM_001195518.2; = p.G208V on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- MMP12 | c.105A>T p.R35S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, varscan2
- MMP9 | c.1881C>A p.F627L | Missense Mutation (SNP) | VAF 166/276 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- MN1 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.056); called by muse, varscan2
- MPPED2 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 126/219 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MRC1 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 139/345 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MRC1 | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 356/852 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPL13 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- MTHFD1L | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by muse, mutect2
- MTIF2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 252/576 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTOR | c.6146A>T p.E2049V | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by mutect2, varscan2
- MTUS1 | c.1893_1895dup p.A632dup | In Frame Ins (INS) | VAF 84/456 reads (18%) | called by mutect2, pindel, varscan2
- MUC12 | c.3227A>T p.Q1076L (on ENST00000379442; = p.Q933L on NM_001164462.1) | Missense Mutation (SNP) | VAF 355/416 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MUC16 | c.22901G>T p.S7634I | Missense Mutation (SNP) | VAF 118/129 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MUC2 | c.1031C>A p.T344N | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- MUC5AC | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 219/659 reads (33%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC5B | c.11141C>G p.S3714C | Missense Mutation (SNP) | VAF 275/612 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUCL1 | c.13C>G p.H5D | Missense Mutation (SNP) | VAF 146/298 reads (49%) | called by muse, mutect2, varscan2
- MYCBPAP | c.1361A>T p.Y454F | Missense Mutation (SNP) | VAF 148/425 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MYH1 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 278/290 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MYH13 | c.4168C>A p.L1390M | Missense Mutation (SNP) | VAF 252/266 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 302/325 reads (93%) | called by muse, mutect2, varscan2
- MYH3 | c.3636dup p.R1213Afs*19 | Frame Shift Ins (INS) | VAF 340/507 reads (67%) | called by mutect2, pindel, varscan2
- MYLK | c.1942+4T>A | Splice Region (SNP) | VAF 486/680 reads (71%) | called by muse, mutect2, varscan2
- MYO1B | c.929G>C p.C310S | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYO1D | c.480C>G p.S160R | Missense Mutation (SNP) | VAF 84/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1G | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- MYOF | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- MYOG | c.597C>A p.H199Q | Missense Mutation (SNP) | VAF 148/159 reads (93%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYOZ1 | c.504A>G p.G168= | Splice Region (SNP) | VAF 118/298 reads (40%) | called by muse, mutect2, varscan2
- MYT1 | c.3238-1G>T p.X1080_splice | Splice Site (SNP) | VAF 79/131 reads (60%) | called by muse, mutect2, varscan2
- NALCN | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 166/269 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBEA | c.3008T>A p.I1003K | Missense Mutation (SNP) | VAF 130/216 reads (60%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NBPF12 | c.2210A>C p.E737A | Missense Mutation (SNP) | VAF 166/609 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NCKAP5 | c.5479C>G p.P1827A | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2
- NCKAP5 | c.5047C>A p.L1683M | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- NCKAP5L | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- NCR3LG1 | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2
- NDST4 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NEB | c.7802G>A p.S2601N | Missense Mutation (SNP) | VAF 366/935 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- NEFM | c.2390A>G p.K797R | Missense Mutation (SNP) | VAF 23/402 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); called by muse, mutect2
- NEK10 | c.2552C>A p.A851D | Missense Mutation (SNP) | VAF 97/101 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NELL1 | c.1838G>T p.C613F | Missense Mutation (SNP) | VAF 82/356 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEUROD1 | c.752del p.A251Efs*11 | Frame Shift Del (DEL) | VAF 293/770 reads (38%) | called by mutect2, pindel, varscan2
- NFASC | c.904C>G p.R302G (on ENST00000339876 / NM_001378329.1; = p.R313G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/113 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- NFIC | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 187/201 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFIC | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 351/365 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NGF | c.683C>G p.A228G | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NKX2-5 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 138/146 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NLGN1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 89/434 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NME8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 175/257 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NOG | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.575A>T p.Q192L | Missense Mutation (SNP) | VAF 137/384 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NPHP1 | c.877T>G p.F293V | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- NPTX1 | c.686A>C p.Q229P | Missense Mutation (SNP) | VAF 189/601 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- NPY5R | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NRP1 | c.1158C>A p.N386K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NRXN3 | c.1791G>T p.E597D (on ENST00000335750 / NM_001330195.2; = p.E224D on NM_004796.6) | Missense Mutation (SNP) | VAF 316/347 reads (91%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NSMF | c.620_626del p.R207Lfs*49 (on ENST00000371475 / NM_001130969.3; = p.R207Lfs*47 on NM_015537.4) | Frame Shift Del (DEL) | VAF 290/669 reads (43%) | called by mutect2, pindel, varscan2
- NTSR1 | c.628C>G p.Q210E | Missense Mutation (SNP) | VAF 110/283 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- OR10AG1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- OR10AG1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, varscan2
- OR10J1 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 203/385 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OR10V1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C3 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 207/431 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR13D1 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- OR1N2 | c.68G>C p.W23S | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- OR2D2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T6 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 108/115 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4C11 | c.501T>A p.C167* | Nonsense Mutation (SNP) | VAF 55/208 reads (26%) | called by muse, mutect2, varscan2
- OR4K17 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 147/441 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- OR4S2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G2 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- OR51Q1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 188/291 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR6C1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 183/330 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6N1 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6P1 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 149/341 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8S1 | c.59A>C p.D20A | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR9I1 | c.437T>A p.V146E | Missense Mutation (SNP) | VAF 115/182 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- OR9K2 | c.364dup p.C122Lfs*15 (on ENST00000305377; = p.C100Lfs*15 on NM_001005243.1) | Frame Shift Ins (INS) | VAF 180/381 reads (47%) | called by mutect2, pindel, varscan2
- P2RY14 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 413/554 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PALLD | c.1714A>T p.S572C | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2
- PAQR5 | c.446A>T p.H149L | Missense Mutation (SNP) | VAF 286/297 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PATL2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PAWR | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PCARE | c.2645T>A p.L882Q | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDHB10 | c.2347A>T p.R783W | Missense Mutation (SNP) | VAF 131/139 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PCDHB15 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 892/949 reads (94%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PCDHB3 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 183/195 reads (94%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCLO | c.5686A>G p.T1896A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PCLO | c.2180A>T p.D727V | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2
- PDCD11 | c.3369-1G>T p.X1123_splice | Splice Site (SNP) | VAF 125/261 reads (48%) | called by muse, mutect2, varscan2
- PDE1C | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PDE5A | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDZRN4 | c.571del p.R191Gfs*37 | Frame Shift Del (DEL) | VAF 119/451 reads (26%) | called by mutect2, pindel, varscan2
- PEAR1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PEG3 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 139/146 reads (95%) | called by muse, mutect2, varscan2
- PEX16 | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 194/341 reads (57%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PFAS | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 155/164 reads (95%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGK2 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PIDD1 | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 18/566 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2
- PIK3R2 | c.1956_1957insT p.G653Wfs*158 | Frame Shift Ins (INS) | VAF 124/179 reads (69%) | called by mutect2, pindel, varscan2
- PITRM1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD2 | c.2136G>T p.L712F | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PKHD1 | c.7128C>A p.Y2376* | Nonsense Mutation (SNP) | VAF 82/457 reads (18%) | called by muse, mutect2, varscan2
- PLA2G1B | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PLB1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 111/382 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCB1 | c.2473A>T p.K825* | Nonsense Mutation (SNP) | VAF 118/279 reads (42%) | called by muse, mutect2, varscan2
- PLCE1 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 124/293 reads (42%) | called by muse, mutect2, varscan2
- PLCL1 | c.470del p.K157Sfs*7 | Frame Shift Del (DEL) | VAF 134/307 reads (44%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLEKHA5 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- PLEKHH2 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PLEKHS1 | c.1349T>A p.F450Y | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- PLEKHS1 | c.1350C>G p.F450L | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLOD1 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 412/424 reads (97%) | called by muse, mutect2, varscan2
- PLOD3 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 82/309 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLSCR2 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 132/627 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLXNA2 | c.4913C>G p.A1638G | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- POTEE | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 237/914 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- POU4F2 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- POU4F2 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 109/186 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, varscan2
- PPP1R9A | c.2833A>T p.K945* | Nonsense Mutation (SNP) | VAF 86/308 reads (28%) | called by mutect2, varscan2
- PPRC1 | c.4756G>T p.V1586F | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF15 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 122/828 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PRF1 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 215/431 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PRG4 | c.3677_3703del p.A1226_K1234del | In Frame Del (DEL) | VAF 94/474 reads (20%) | called by mutect2, pindel
- PRKCSH | c.1249_1258dup p.T420Rfs*50 | Frame Shift Ins (INS) | VAF 90/164 reads (55%) | called by mutect2, varscan2
- PRKN | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 298/317 reads (94%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRLR | c.1461C>A p.D487E | Missense Mutation (SNP) | VAF 386/573 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PROM2 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 185/409 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRSS1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 132/745 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PSMD8 | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTBP2 | c.1390A>C p.T464P (on ENST00000426398 / NM_001300986.2; = p.T456P on NM_021190.4) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTCD1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PTCHD4 | c.2236C>G p.Q746E | Missense Mutation (SNP) | VAF 171/295 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTGIS | c.446T>A p.L149* | Nonsense Mutation (SNP) | VAF 70/185 reads (38%) | called by muse, mutect2, varscan2
- PTPN12 | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PTPRA | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRB | c.3832G>C p.A1278P | Missense Mutation (SNP) | VAF 185/265 reads (70%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PTPRB | c.2612C>A p.T871N | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PTPRH | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 304/322 reads (94%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PTPRM | c.4094T>C p.L1365S | Missense Mutation (SNP) | VAF 242/543 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRZ1 | c.3377A>T p.Q1126L | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PURG | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 116/320 reads (36%) | called by muse, mutect2, varscan2
- PXDN | c.2273C>A p.A758D | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PXYLP1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 85/358 reads (24%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RAB3IP | c.622G>T p.E208* (on ENST00000550536 / NM_175623.4; = p.E192* on NM_022456.5) | Nonsense Mutation (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- RAD51AP2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 144/331 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RADIL | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAP1GAP2 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- RASSF4 | c.760A>T p.R254W | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RASSF9 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 99/161 reads (61%) | called by muse, mutect2, varscan2
- RB1 | c.2520+2dup p.X840_splice | Splice Site (INS) | VAF 9/86 reads (10%) | called by pindel, varscan2
- RECQL4 | c.2980G>C p.D994H | Missense Mutation (SNP) | VAF 145/325 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RERE | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RESP18 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 139/303 reads (46%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RGS21 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RICTOR | c.2114T>C p.L705S | Missense Mutation (SNP) | VAF 151/232 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.776A>T p.Y259F (on ENST00000666250 / NM_001348490.2; = p.Y67F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RNF207 | c.1706A>G p.D569G | Missense Mutation (SNP) | VAF 122/625 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
538 further variants in this file (163 protein-altering or splice-affecting, 245 silent, 130 other) are not listed here.
